Somatic mutation profile of tumor specimen MMRF_2085_2_BM_CD138pos (aliquot MMRF_2085_2_BM_CD138pos_T1_KHS5U_L11243) from MMRF case MMRF_2085, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.7 years (27,278 days).
Specimen MMRF_2085_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7e98299-9b42-4489-80d7-1e3d629767c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2085_2_PB_WBC (Blood Derived Normal), aliquot MMRF_2085_2_PB_WBC_C2_KHS5U_L11244; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb628c66-641a-4076-9b8d-2313eaf0c1de

The open-access MAF lists 103 somatic variants for this specimen: 37 protein-altering or splice-affecting, 7 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 38, Missense Mutation 32, Intron 11, Silent 7, RNA 4, 5'UTR 3, Nonsense Mutation 3, 3'Flank 2, 5'Flank 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BET1L | c.55C>G p.R19G | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs144624940; called by muse, mutect2
- C8G | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | catalogued as rs1375829208; called by muse, mutect2
- EIF4G3 | c.907C>T p.L303F | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1288974207; called by muse, mutect2
- FLRT2 | c.1021G>A p.G341S | Missense Mutation (SNP) | VAF 15/207 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as COSV100420191; called by muse, mutect2
- HBD | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 33/294 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.463); catalogued as COSV53081947; called by muse, mutect2, varscan2
- HDAC11 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs762810161, COSV99849979; called by muse, mutect2, varscan2
- HDC | c.1940C>G p.S647C | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.221); catalogued as rs1567443266; called by muse, mutect2
- IL17RD | c.1729C>A p.P577T | Missense Mutation (SNP) | VAF 17/221 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.158); catalogued as rs766095716; called by muse, mutect2
- ITGB2 | c.1832G>A p.R611H (on ENST00000302347; = p.R587H on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs772406915; called by muse, mutect2, varscan2
- OR9Q2 | c.723C>A p.C241* | Nonsense Mutation (SNP) | VAF 33/368 reads (9%) | catalogued as rs149505103, COSV61112628; called by muse, mutect2
- RFX1 | c.1168G>A p.G390S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs761840229; called by muse, mutect2, varscan2
- SETDB1 | c.3728G>T p.R1243L | Missense Mutation (SNP) | VAF 21/472 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54977297; called by muse, mutect2
- THBS2 | c.2333A>T p.N778I | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64677236; called by muse, mutect2, varscan2
- AC138647.1 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.06); called by muse, mutect2
- AKAP6 | c.6415C>G p.L2139V | Missense Mutation (SNP) | VAF 6/182 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); called by muse, mutect2
- ATP8B3 | c.104A>C p.Q35P | Missense Mutation (SNP) | VAF 47/345 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- AVPR1A | c.559T>C p.F187L | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2
- CDK13 | c.3879C>G p.D1293E | Missense Mutation (SNP) | VAF 9/246 reads (4%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.584); called by muse, mutect2
- CILP | c.1745T>A p.M582K | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- CLCA4 | c.1889C>T p.T630I | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.893); called by muse, mutect2
- COMMD4 | c.482_490del p.V161_A163del | In Frame Del (DEL) | VAF 18/138 reads (13%) | called by mutect2, pindel, varscan2
- CRACD | c.2636C>T p.A879V | Missense Mutation (SNP) | VAF 23/259 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2
- FMNL1 | c.475T>G p.C159G | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2
- GJA10 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- HMCN2 | c.947G>T p.R316L | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2
- IGSF10 | c.2479A>G p.T827A | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- KLHL2 | c.1154A>G p.N385S | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- LDLR | c.2272G>T p.G758W | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2
- PCDHA2 | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.192); called by muse, mutect2
- PCLO | c.8436C>A p.S2812R | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- PRPS1L1 | c.634A>C p.N212H | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- RPS2 | c.177+4G>C | Splice Region (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- SIPA1L3 | c.4955G>T p.S1652I | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SPINK5 | c.1596T>A p.C532* | Nonsense Mutation (SNP) | VAF 12/177 reads (7%) | called by muse, mutect2
- SPNS2 | c.1490A>G p.E497G | Missense Mutation (SNP) | VAF 14/313 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- TIAM1 | c.1321G>T p.A441S | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.998); called by muse, mutect2
- WDR87 | c.2795A>G p.N932S | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- COL9A3 | c.822G>T p.G274= | Silent (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- DNAH1 | c.4105C>T p.L1369= | Silent (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- LARP6 | c.1065C>T p.H355= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as rs781281490, COSV54582762; called by muse, mutect2, varscan2
- PON3 | c.456G>A p.L152= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV99672566; called by muse, mutect2
- RINL | c.1224C>T p.S408= (on ENST00000591812 / NM_001195833.2; = p.S294= on NM_198445.4) | Silent (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- SH2D4A | c.109C>A p.R37= | Silent (SNP) | VAF 12/180 reads (7%) | catalogued as COSV56125006; called by muse, mutect2
- SHANK1 | c.3840G>A p.P1280= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs887704440; called by muse, mutect2, varscan2
- AC244197.3 | c.*3109G>T | 3'UTR (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- ADAM30 | c.-99G>C | 5'UTR (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- ANKRD34B | c.*744G>A | 3'UTR (SNP) | VAF 33/147 reads (22%) | called by muse, mutect2, varscan2
- ASXL2 | c.*2207C>G | 3'UTR (SNP) | VAF 13/176 reads (7%) | called by muse, mutect2
- BAZ2A | c.2755-77A>G | Intron (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- BLACE | n.2122C>G | RNA (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- BLACE | n.1247G>A | RNA (SNP) | VAF 9/100 reads (9%) | catalogued as rs1427148481; called by muse, mutect2
- CACNG8 | c.*1691C>T | 3'UTR (SNP) | VAF 12/122 reads (10%) | catalogued as rs914907368; called by muse, mutect2
- CCND2 | c.*5174T>C | 3'UTR (SNP) | VAF 9/111 reads (8%) | called by muse, mutect2
- CDC42BPA | c.*568A>T | 3'UTR (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- CDHR1 | chr10:84219316 C>A | 3'Flank (SNP) | VAF 41/720 reads (6%) | catalogued as rs972451594; called by muse, mutect2
- CIB4 | c.187-10212G>A | Intron (SNP) | VAF 15/153 reads (10%) | catalogued as COSV56599084; called by muse, mutect2
- CTNNA2 | c.*59A>C | 3'UTR (SNP) | VAF 19/117 reads (16%) | catalogued as rs1034832041; called by muse, mutect2, varscan2
- DCHS2 | n.4706A>G | RNA (SNP) | VAF 12/255 reads (5%) | called by muse, mutect2
- DTX1 | c.-208A>G | 5'UTR (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- GABRE | c.*1390del | 3'UTR (DEL) | VAF 39/144 reads (27%) | called by mutect2, pindel, varscan2
- GGA1 | c.*761G>A | 3'UTR (SNP) | VAF 7/109 reads (6%) | catalogued as rs965727653; called by muse, mutect2
- GREM2 | c.*2715C>A | 3'UTR (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- GSN | c.667-151T>G | Intron (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- HNRNPA2B1 | c.877+37G>A | Intron (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- HUNK | c.*4019G>T | 3'UTR (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- IPCEF1 | c.*776G>A | 3'UTR (SNP) | VAF 8/81 reads (10%) | catalogued as rs890836951; called by muse, mutect2, varscan2
- KCNJ3 | c.*1964del | 3'UTR (DEL) | VAF 10/86 reads (12%) | called by mutect2, pindel, varscan2
- KDSR | c.*654A>G | 3'UTR (SNP) | VAF 6/84 reads (7%) | catalogued as rs1459979105; called by muse, mutect2
- LIFR | c.*6203T>A | 3'UTR (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- LRRIQ3 | c.573+1811A>G | Intron (SNP) | VAF 24/320 reads (8%) | called by muse, mutect2
- LY6K | c.*871T>A | 3'UTR (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- MLLT10 | c.240+18105T>C | Intron (SNP) | VAF 5/99 reads (5%) | called by muse, mutect2
- MMP16 | c.*3040C>A | 3'UTR (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- MRAS | c.*1625G>C | 3'UTR (SNP) | VAF 14/133 reads (11%) | called by muse, mutect2
- NEDD1 | c.*69A>G | 3'UTR (SNP) | VAF 34/348 reads (10%) | called by muse, mutect2
- NEURL1B | c.*387A>T | 3'UTR (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- NFU1 | chr2:69437542 C>T | 5'Flank (SNP) | VAF 12/112 reads (11%) | catalogued as rs557744910; called by muse, mutect2, varscan2
- NOTCH1 | c.*804C>T | 3'UTR (SNP) | VAF 13/121 reads (11%) | catalogued as rs1190490511; called by muse, mutect2, varscan2
- POU2F2 | chr19:42088610 C>G | 3'Flank (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- PTCHD4 | c.908-21419T>C | Intron (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
- PTPN12 | c.2281+34G>A | Intron (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- PYCR3 | c.*1025C>T | 3'UTR (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- PYCR3 | c.*1024G>A | 3'UTR (SNP) | VAF 7/133 reads (5%) | called by muse, mutect2
- RAB2A | c.*1106C>T | 3'UTR (SNP) | VAF 8/123 reads (7%) | called by muse, mutect2
- RAB35 | c.*1040C>T | 3'UTR (SNP) | VAF 8/69 reads (12%) | catalogued as rs940045069; called by muse, mutect2
- RBM33 | c.*3975C>T | 3'UTR (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- RBM38 | c.*1392T>C | 3'UTR (SNP) | VAF 15/100 reads (15%) | called by muse, mutect2, varscan2
- RPS4XP21 | n.669C>T | RNA (SNP) | VAF 14/170 reads (8%) | catalogued as rs562456841; called by muse, mutect2
- SCAMP4 | c.-42+24C>G | Intron (SNP) | VAF 9/150 reads (6%) | called by muse, mutect2
- SEPTIN12 | c.374+23_374+24insA | Intron (INS) | VAF 6/45 reads (13%) | called by mutect2, pindel
- SLC25A51P4 | n.1463+522T>C | Intron (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- SLC7A7 | c.*31G>A | 3'UTR (SNP) | VAF 22/303 reads (7%) | catalogued as rs929919094; called by muse, mutect2
- SLC9A2 | c.*991A>G | 3'UTR (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- SLF2 | c.*2963C>T | 3'UTR (SNP) | VAF 14/124 reads (11%) | called by muse, mutect2
- SMAD7 | c.*773G>A | 3'UTR (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- SOSTDC1 | c.*182A>G | 3'UTR (SNP) | VAF 9/85 reads (11%) | catalogued as rs1297208246; called by muse, mutect2, varscan2
- TEAD3 | c.*993G>A | 3'UTR (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- TMED9 | c.*164A>G | 3'UTR (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2
- TMEM115 | c.-353C>A | 5'UTR (SNP) | VAF 16/250 reads (6%) | called by muse, mutect2
- TNFAIP2 | c.*1653C>G | 3'UTR (SNP) | VAF 26/266 reads (10%) | called by muse, mutect2
- TRIM24 | c.*730G>C | 3'UTR (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- UVRAG | c.*1284T>C | 3'UTR (SNP) | VAF 7/124 reads (6%) | catalogued as rs1368216978; called by muse, mutect2
- YWHAQ | c.*592G>A | 3'UTR (SNP) | VAF 12/274 reads (4%) | called by muse, mutect2
